Somatic mutation profile of tumor specimen TCGA-06-0209-01A (aliquot TCGA-06-0209-01A-01D-1491-08) from TCGA case TCGA-06-0209, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 76.3 years (27,877 days).
Specimen TCGA-06-0209-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e26e899-c103-4bc2-801e-87ecb8db45ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0209-10A (Blood Derived Normal), aliquot TCGA-06-0209-10A-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d85839ef-a9ff-48f1-b5db-6df4bdff9aa0

The open-access MAF lists 77 somatic variants for this specimen: 55 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 20, Nonsense Mutation 3, Splice Site 2, Intron 1, 5'Flank 1, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGAP3 | c.2179C>T p.R727C (on ENST00000622464; = p.R763C on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs372948404; called by muse, mutect2, varscan2
- ARAP3 | c.3082C>T p.R1028C | Missense Mutation (SNP) | VAF 62/257 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs754482035, COSV53355452; called by muse, mutect2, varscan2
- BCL11B | c.698C>T p.A233V (on ENST00000357195 / NM_001282237.2; = p.A162V on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61740186; called by muse, mutect2, varscan2
- CALCR | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.066); catalogued as rs763907185, COSV64006591; called by muse, mutect2, varscan2
- CCP110 | c.982C>T p.R328* | Nonsense Mutation (SNP) | VAF 48/153 reads (31%) | catalogued as rs1462705993, COSV66818143; called by muse, mutect2, varscan2
- COL6A6 | c.5041G>A p.D1681N | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as COSV62039290; called by muse, mutect2, varscan2
- COL7A1 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs146041612, COSV100097885; called by muse, mutect2, varscan2
- CSDE1 | c.1385A>G p.D462G (on ENST00000358528 / NM_001007553.3; = p.D431G on NM_007158.6) | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.029); catalogued as COSV54762356; called by muse, mutect2, varscan2
- CYP4A11 | c.852G>C p.K284N | Missense Mutation (SNP) | VAF 89/267 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV60226009; called by muse, mutect2, varscan2
- DSG3 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs137884016; called by muse, mutect2, varscan2
- GLI2 | c.3656G>A p.G1219D (on ENST00000361492 / NM_001374353.1; = p.G1236D on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.127); catalogued as COSV58052608; called by muse, mutect2, varscan2
- GLYATL1 | c.669G>A p.M223I (on ENST00000317391 / NM_001354699.1; = p.M254I on NM_080661.4) | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as COSV55610652, COSV55611802; called by muse, mutect2, varscan2
- GNG2 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 67/279 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs139067662, COSV58915554; called by muse, mutect2, varscan2
- GRIP1 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs367635870; called by muse, mutect2, varscan2
- HDC | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764847892, COSV51071224; called by muse, mutect2, varscan2
- IFT57 | c.253T>A p.Y85N | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as COSV52712645; called by muse, mutect2, varscan2
- IKZF1 | c.1273G>A p.G425R | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1459868445, COSV58792366; called by muse, mutect2, varscan2
- KDM7A | c.752T>A p.V251E | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50097670; called by muse, mutect2, varscan2
- KIF3A | c.1516G>T p.E506* | Nonsense Mutation (SNP) | VAF 166/509 reads (33%) | catalogued as COSV66416801; called by muse, mutect2, varscan2
- KRTAP19-4 | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 31/221 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV61859767; called by muse, mutect2, varscan2
- LRP1 | c.11842G>T p.G3948C | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV54528251; called by muse, mutect2, varscan2
- LRP6 | c.2641G>A p.V881I | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs767098954, COSV53783132, COSV53786022; called by muse, varscan2
- LTBP2 | c.4693C>T p.R1565C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs750269632, COSV56213070; called by muse, mutect2, varscan2
- METTL17 | c.38G>C p.R13T | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59557224; called by muse, mutect2, varscan2
- METTL17 | c.140G>C p.R47T | Missense Mutation (SNP) | VAF 44/225 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV59557232; called by muse, mutect2, varscan2
- MRPS12 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140018981, COSV55500413; called by muse, mutect2, varscan2
- MUC16 | c.34604C>T p.T11535M | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.818); catalogued as rs111231164, COSV67472305; called by muse, mutect2, varscan2
- NOBOX | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.145); catalogued as rs558507338, COSV56193178; called by muse, mutect2, varscan2
- NR3C2 | c.2483A>G p.Y828C | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.971); catalogued as rs756059941, COSV60985119; called by muse, mutect2, varscan2
- NRK | c.1312C>T p.R438* | Nonsense Mutation (SNP) | VAF 25/48 reads (52%) | catalogued as COSV54593617, COSV54598004; called by muse, mutect2, varscan2
- OGFOD1 | c.1609T>C p.S537P | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV60201631; called by muse, mutect2, varscan2
- OPRM1 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.386); catalogued as rs187512719, COSV57674395; called by muse, mutect2, varscan2
- OR4P4 | c.238A>G p.M80V | Missense Mutation (SNP) | VAF 70/283 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV58923778; called by muse, mutect2, varscan2
- POTEF | c.402C>G p.H134Q | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); catalogued as rs200168896, COSV104417597, COSV62545047; called by muse, varscan2
- PSG5 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 100/579 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as COSV61655552; called by muse, mutect2, varscan2
- PSMC1 | c.1102C>T p.H368Y | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV54322311; called by muse, mutect2, varscan2
- QRICH2 | c.4136G>A p.R1379H | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772000651, COSV53154869, COSV53158477; called by muse, mutect2, varscan2
- RBM33 | c.2887G>T p.V963L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.338); catalogued as COSV56637713; called by muse, mutect2, varscan2
- RBM38 | c.392C>G p.P131R | Missense Mutation (SNP) | VAF 52/347 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV61135423; called by muse, mutect2, varscan2
- SDK1 | c.1724C>A p.S575Y | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0.309); catalogued as COSV67390746; called by muse, mutect2
- SERPINA3 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 56/232 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.432); catalogued as rs752346883, COSV67587323; called by muse, mutect2, varscan2
- SZT2 | c.7459C>T p.P2487S (on ENST00000634258 / NM_001365999.1; = p.P2430S on NM_015284.4) | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.318); catalogued as COSV65175318; called by muse, mutect2, varscan2
- TRPC6 | c.1675G>A p.D559N | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.199); catalogued as COSV60261822; called by muse, mutect2, varscan2
- UPP2 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773369298, COSV50050075; called by muse, mutect2, varscan2
- USP28 | c.2400+2T>C p.X800_splice | Splice Site (SNP) | VAF 5/62 reads (8%) | catalogued as COSV50196818; called by muse, mutect2
- VEZF1 | c.569A>G p.N190S | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs745913326, COSV51969904; called by muse, mutect2, varscan2
- VSTM2A | c.635G>C p.G212A | Missense Mutation (SNP) | VAF 319/331 reads (96%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs749130574, COSV68291105; called by muse, mutect2, varscan2
- XRCC1 | c.1141G>A p.V381M | Missense Mutation (SNP) | VAF 50/255 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs2271980, COSV53449042; called by muse, varscan2
- ZAN | c.3662G>A p.S1221N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV61817815; called by muse, mutect2, varscan2
- ZNF165 | c.178T>C p.S60P | Missense Mutation (SNP) | VAF 55/193 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV66103051; called by muse, mutect2, varscan2
- ZNF546 | c.1790_1793del p.T597Nfs*172 | Frame Shift Del (DEL) | VAF 17/114 reads (15%) | catalogued as rs1568389347; called by mutect2, pindel, varscan2
- APOB | c.1352+1del p.X451_splice | Splice Site (DEL) | VAF 36/193 reads (19%) | called by mutect2, pindel, varscan2
- NPTXR | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.076); called by muse, varscan2
- PIGU | c.943_945del p.F315del | In Frame Del (DEL) | VAF 15/55 reads (27%) | called by pindel, varscan2
- SH2D1A | c.325dup p.R109Kfs*14 | Frame Shift Ins (INS) | VAF 30/184 reads (16%) | called by mutect2, pindel, varscan2
- ALPK2 | c.3477G>A p.T1159= | Silent (SNP) | VAF 64/314 reads (20%) | catalogued as rs766930523, COSV64497878; called by muse, mutect2, varscan2
- CACNG3 | c.267C>T p.Y89= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as rs368528326, COSV50086161; called by muse, mutect2, varscan2
- IGHM | c.54G>A p.P18= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs569451306; called by muse, mutect2, varscan2
- KCNJ3 | c.975T>C p.H325= | Silent (SNP) | VAF 43/185 reads (23%) | catalogued as rs1275817235, COSV54545833; called by muse, mutect2, varscan2
- LGR6 | c.1896C>T p.Y632= (on ENST00000367278 / NM_001017403.1; = p.Y580= on NM_021636.3) | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs540125583, COSV55157415; called by muse, mutect2, varscan2
- MAP2K7 | c.462C>T p.S154= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs373551377; called by muse, mutect2, varscan2
- MROH7 | c.1431C>T p.S477= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs769296346, COSV59873771; called by muse, mutect2, varscan2
- MUC3A | c.8304C>T p.P2768= | Silent (SNP) | VAF 57/672 reads (8%) | catalogued as rs755010363, COSV60222402; called by muse, mutect2
- NEXMIF | c.783C>T p.F261= | Silent (SNP) | VAF 123/206 reads (60%) | catalogued as rs768534908, COSV50022266; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR1C1 | c.222G>A p.T74= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs779254162, COSV68716341; called by muse, mutect2, varscan2
- OR56A4 | c.42G>A p.Q14= | Silent (SNP) | VAF 41/197 reads (21%) | catalogued as COSV58110435; called by muse, mutect2, varscan2
- OVCH1 | c.1494C>T p.T498= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1262116288, COSV58963007; called by muse, mutect2, varscan2
- PCDHA2 | c.2253G>A p.S751= | Silent (SNP) | VAF 50/112 reads (45%) | catalogued as rs782152702, COSV65371636; called by muse, mutect2, varscan2
- SIM1 | c.1350G>A p.A450= | Silent (SNP) | VAF 47/163 reads (29%) | catalogued as COSV53492624, COSV99492011; called by muse, mutect2, varscan2
- SNAP91 | c.2037G>A p.A679= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs202058742, COSV52136154; called by muse, mutect2
- SPOCK1 | c.766T>C p.L256= | Silent (SNP) | VAF 57/167 reads (34%) | catalogued as rs373166420; called by muse, mutect2, varscan2
- TCHH | c.1602C>T p.S534= | Silent (SNP) | VAF 50/228 reads (22%) | catalogued as COSV64278173; called by muse, mutect2, varscan2
- TTN | c.74865C>T p.S24955= (on ENST00000591111; = p.S17531= on NM_003319.4) | Silent (SNP) | VAF 64/322 reads (20%) | catalogued as rs777989882, COSV60086879; ClinVar: likely benign; called by muse, mutect2, varscan2
- TWNK | c.1401A>G p.Q467= | Silent (SNP) | VAF 31/190 reads (16%) | catalogued as rs780481249, COSV52972618; called by muse, mutect2, varscan2
- XYLT2 | c.1320G>A p.T440= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as rs373704915, COSV50022186; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504335 A>G | 5'Flank (SNP) | VAF 12/52 reads (23%) | called by muse, varscan2
- CDC42BPA | c.4791+5164C>T | Intron (SNP) | VAF 4/38 reads (11%) | catalogued as rs760950814, COSV100505165; called by mutect2, varscan2
